Somatic mutation profile of tumor specimen MP2PRT-PAVSTN-TMP1-A (aliquot MP2PRT-PAVSTN-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVSTN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,431 days).
Specimen MP2PRT-PAVSTN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae5ec392-ac55-490e-9eb1-ee248815cf6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSTN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSTN-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3fefaa2-4cb2-407f-9df0-5181351bca64

The open-access MAF lists 99 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 24, Nonsense Mutation 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 25/942 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1488285678, COSV57073589; called by muse, mutect2
- ANKRD31 | c.4684G>C p.E1562Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1189525418; called by muse, mutect2
- ATAD2 | c.3792G>C p.L1264F | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.078); catalogued as COSV54881638, COSV54882981; called by muse, mutect2, varscan2
- BSX | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 120/800 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58005629; called by muse, mutect2, varscan2
- C7 | c.1220C>A p.A407E | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437433027; called by muse, mutect2, varscan2
- CACNA1H | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 46/1227 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.123); catalogued as rs1303029428; called by muse, mutect2
- CREBBP | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 29/502 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV52136246; called by muse, mutect2
- DDX42 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs1192737676; called by muse, mutect2, varscan2
- DNAH9 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 212/998 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1490528559, COSV52370597; called by muse, mutect2, varscan2
- EML6 | c.2072G>A p.R691K | Missense Mutation (SNP) | VAF 18/425 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV62867866; called by muse, mutect2
- ENDOD1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1435173793; called by muse, mutect2
- FAM83B | c.2186C>G p.S729C | Missense Mutation (SNP) | VAF 9/304 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV100174225; called by muse, mutect2
- GSDME | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 17/515 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV61652838; called by muse, mutect2
- KIF4A | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV65542331; called by muse, mutect2, varscan2
- NOTUM | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 142/442 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68825880; called by muse, mutect2, varscan2
- ORC3 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV57640859; called by muse, mutect2, varscan2
- PATJ | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57173739; called by muse, mutect2, varscan2
- PCDHA7 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 15/561 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368032433, COSV65338759; called by muse, mutect2
- PKHD1 | c.2597C>G p.S866C | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs776017473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNB1 | c.2720C>T p.T907I | Missense Mutation (SNP) | VAF 171/559 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs763782209; called by muse, mutect2, varscan2
- RAD51B | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101185389; called by muse, mutect2, varscan2
- RADIL | c.1186C>G p.Q396E | Missense Mutation (SNP) | VAF 58/1061 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68201578; called by muse, mutect2
- RPGRIP1L | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1210120285; called by muse, mutect2, varscan2
- RUSF1 | c.861G>C p.L287F | Missense Mutation (SNP) | VAF 211/996 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.162); catalogued as COSV57890397; called by muse, mutect2, varscan2
- SCN9A | c.5692C>T p.R1898C (on ENST00000303354; = p.R1887C on NM_002977.3) | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs577823520, COSV57619186; ClinVar: uncertain significance; called by muse, mutect2
- SLCO5A1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 48/936 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs767975463; called by muse, mutect2
- SLX4 | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 237/823 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as COSV53565104, COSV53566925; called by muse, mutect2, varscan2
- SYNE1 | c.6622G>A p.E2208K (on ENST00000367255 / NM_182961.4; = p.E2215K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs1364570078, COSV55101408; called by muse, mutect2
- TSHZ1 | c.1389G>C p.E463D (on ENST00000580243 / NM_001308210.2; = p.E418D on NM_005786.6) | Missense Mutation (SNP) | VAF 20/820 reads (2%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1445054792; called by muse, mutect2
- TTN | c.89418G>C p.K29806N (on ENST00000591111; = p.K22382N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/410 reads (5%) | PolyPhen possibly damaging (0.856); catalogued as rs1169915824; called by muse, mutect2
- ZNF407 | c.5960C>T p.S1987L | Missense Mutation (SNP) | VAF 110/698 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55250326; called by muse, mutect2, varscan2
- ACIN1 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 17/546 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANKRD60 | c.972G>T p.M324I | Missense Mutation (SNP) | VAF 30/694 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- BICD2 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 42/1003 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C1orf74 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- CBY2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); called by muse, varscan2
- CDC14A | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CYP2B6 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- EDF1 | c.9G>C p.E3D | Missense Mutation (SNP) | VAF 108/791 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- F7 | c.156C>G p.H52Q | Missense Mutation (SNP) | VAF 228/721 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLRT2 | c.399G>C p.L133F | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.404); called by muse, mutect2
- FREM2 | c.5927C>A p.T1976N | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- H1-3 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 117/406 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP1 | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 17/509 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- HNRNPK | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- HPS6 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 92/575 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- IRF2BPL | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 34/1223 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2
- KCNC1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 93/1197 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2
- KIFC1 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 47/1130 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIR2DS4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LAMA2 | c.7393G>C p.D2465H | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LIPH | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- LTBP4 | c.4072G>A p.D1358N (on ENST00000308370 / NM_001042544.1; = p.D1321N on NM_003573.2) | Missense Mutation (SNP) | VAF 90/681 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MBTPS2 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, varscan2
- MED23 | c.1600C>G p.H534D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRGPRX1 | c.17C>G p.S6* | Nonsense Mutation (SNP) | VAF 28/533 reads (5%) | called by muse, mutect2
- MTUS1 | c.2737G>A p.E913K (on ENST00000262102 / NM_001363061.1; = p.E79K on NM_020749.4) | Missense Mutation (SNP) | VAF 24/618 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- NEGR1 | c.1038C>G p.F346L | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIN | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 24/639 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NIPAL4 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PCDH7 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 113/738 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PDZRN3 | c.909G>C p.R303S | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2
- PHF3 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- POLR1A | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 91/535 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PPTC7 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- RAD51B | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2
- SLC35F4 | c.1165G>T p.V389L (on ENST00000339762 / NM_001352015.2; = p.V353L on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 184/533 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLC38A4 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TNC | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 78/995 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF236 | c.4158T>G p.I1386M | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF623 | c.309C>G p.N103K | Missense Mutation (SNP) | VAF 205/667 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CTTNBP2 | c.3207G>A p.A1069= | Silent (SNP) | VAF 117/624 reads (19%) | catalogued as rs767932676; called by muse, mutect2, varscan2
- DNM3 | c.2205G>A p.L735= (on ENST00000355305 / NM_001350206.2; = p.L729= on NM_015569.5) | Silent (SNP) | VAF 72/479 reads (15%) | called by muse, mutect2, varscan2
- EPOP | c.459C>T p.F153= | Silent (SNP) | VAF 40/1508 reads (3%) | called by muse, mutect2
- GNPTG | c.474C>G p.V158= | Silent (SNP) | VAF 27/788 reads (3%) | called by muse, mutect2
- GPN1 | c.762C>T p.L254= | Silent (SNP) | VAF 90/263 reads (34%) | catalogued as COSV53117706; called by muse, mutect2, varscan2
- ITGB7 | c.2331C>G p.L777= | Silent (SNP) | VAF 68/306 reads (22%) | catalogued as rs866051705; called by muse, mutect2, varscan2
- JOSD2 | c.540G>A p.E180= | Silent (SNP) | VAF 197/712 reads (28%) | catalogued as rs1350032855; called by muse, mutect2, varscan2
- KLF18 | c.2463C>T p.L821= | Silent (SNP) | VAF 23/745 reads (3%) | called by muse, mutect2
- MAFA | c.282C>A p.P94= | Silent (SNP) | VAF 14/279 reads (5%) | called by muse, mutect2
- NUTM2D | c.1911G>A p.L637= | Silent (SNP) | VAF 118/949 reads (12%) | catalogued as rs1208109318; called by muse, mutect2, varscan2
- PANK4 | c.2061G>A p.R687= | Silent (SNP) | VAF 40/997 reads (4%) | called by muse, mutect2
- PNCK | c.663C>T p.F221= (on ENST00000340888 / NM_001366975.1; = p.F304= on NM_001039582.3) | Silent (SNP) | VAF 126/378 reads (33%) | called by muse, mutect2, varscan2
- PTCHD3 | c.1008C>T p.D336= | Silent (SNP) | VAF 64/651 reads (10%) | catalogued as COSV71256346; called by muse, varscan2
- PTPRQ | c.3882C>T p.I1294= (on ENST00000616559; = p.I1252= on NM_001145026.2) | Silent (SNP) | VAF 42/272 reads (15%) | catalogued as rs1322520450; called by muse, mutect2, varscan2
- SAMD3 | c.1464C>T p.F488= | Silent (SNP) | VAF 53/412 reads (13%) | called by muse, mutect2, varscan2
- SCN8A | c.3258C>T p.F1086= | Silent (SNP) | VAF 21/539 reads (4%) | called by muse, mutect2
- SLC12A9 | c.1549C>T p.L517= | Silent (SNP) | VAF 111/602 reads (18%) | catalogued as COSV99307712; called by muse, mutect2, varscan2
- SLC6A17 | c.210C>T p.I70= | Silent (SNP) | VAF 27/663 reads (4%) | called by muse, mutect2
- SPEN | c.5238G>A p.E1746= | Silent (SNP) | VAF 25/748 reads (3%) | called by muse, mutect2
- SSH2 | c.2304G>A p.L768= | Silent (SNP) | VAF 11/303 reads (4%) | catalogued as COSV52170518; called by muse, mutect2
- TTC7A | c.117G>A p.L39= | Silent (SNP) | VAF 184/1029 reads (18%) | catalogued as COSV55411447; called by muse, mutect2, varscan2
- WNK2 | c.4968C>T p.P1656= (on ENST00000297954 / NM_001282394.1; = p.P1619= on NM_006648.3) | Silent (SNP) | VAF 87/554 reads (16%) | called by muse, varscan2
- ZCCHC2 | c.1425T>A p.S475= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, varscan2
- ZSCAN1 | c.201G>A p.L67= | Silent (SNP) | VAF 40/1142 reads (4%) | catalogued as rs1262182473, COSV56606996; called by muse, mutect2
- LRGUK | c.1843+8273G>C | Intron (SNP) | VAF 46/584 reads (8%) | called by muse, mutect2
- RAVER1 | c.1431+195G>A | Intron (SNP) | VAF 174/1033 reads (17%) | called by muse, mutect2, varscan2
- TEX35 | c.-1C>T | 5'UTR (SNP) | VAF 17/512 reads (3%) | called by muse, mutect2
